Gene-level copy-number profile of tumor specimen MP2PRT-PASRBU-TMP1-A from MP2PRT case MP2PRT-PASRBU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,988 days).
Specimen MP2PRT-PASRBU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b8582787-9965-4e5f-9f09-a09719eb256e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASRBU-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/9a75f38c-5867-4718-8a01-89cd355ccdfd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 226; copy number 1: 388; copy number 2: 56,975; copy number 3: 799.

Homozygous deletions (total copy number 0; autosomes only): 226 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,295,455, 41 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV6-21, IGKV1-22, IGKV2-23, IGKV3-25, IGKV2-26, AC244255.1, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36.
- chr2:89,959,979–89,990,221, 4 genes: IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25.
- chr2:90,121,786–90,173,414, 4 genes: IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11.
- chr3:37,182,107–37,244,177, 4 genes (within-gene range 0–2): AC126118.1, AC097359.1, AC097359.3, AC097359.2.
- chr3:37,275,693–37,276,598, 1 gene (within-gene range 0–2): TCEA1P2.
- chr5:158,225,352–159,099,916, 10 genes: AC025437.3, AC025437.2, AC025437.1, LINC02227, AC091979.1, AC091979.2, AC091939.1, EBF1, AC136424.2, AC136424.1.
- chr10:109,996,368–110,135,565, 1 gene (within-gene range 0–2): ADD3.
- chr11:64,185,272–64,269,150, 13 genes: STIP1, FERMT3, TRPT1, NUDT22, AP001453.1, DNAJC4, VEGFB, FKBP2, AP001453.3, PPP1R14B, PPP1R14B-AS1, AP001453.2, PLCB3.
- chr14:22,438,547–22,459,156, 7 genes (within-gene range 0–2): TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3.
- chr14:22,483,004–22,511,024, 23 genes (within-gene range 0–2): TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31.
- chr14:105,672,308–106,481,706, 116 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–2): IGHVIII-47-1, IGHV3-48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 388. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
